Somatic mutation profile of tumor specimen TCGA-EM-A4FM-01A (aliquot TCGA-EM-A4FM-01A-11D-A257-08) from TCGA case TCGA-EM-A4FM, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 59.1 years (21,595 days).
Specimen TCGA-EM-A4FM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20643898-5c50-4f6a-8e2f-0d8bd49dc322.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A4FM-10A (Blood Derived Normal), aliquot TCGA-EM-A4FM-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd566334-307c-4b7e-bb95-e922bcee1522

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCDC144A | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1170326497, COSV100138767; called by muse, mutect2, varscan2
- DCAF8L1 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV71595136; called by muse, mutect2, varscan2
- IL2RG | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52147260; called by muse, mutect2, varscan2
- LRFN4 | c.1322G>A p.S441N | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.958); catalogued as COSV58920774; called by muse, mutect2, varscan2
- MAGEA11 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60753815; called by muse, mutect2, varscan2
- MYH2 | c.940C>G p.P314A | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV55432133, COSV55434290, COSV99820512; called by muse, mutect2, varscan2
- PCDHA10 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV56479731, COSV56488368; called by muse, mutect2, varscan2
- PCSK7 | c.1001A>G p.N334S | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.084); catalogued as COSV58005935; called by muse, mutect2
- PKHD1 | c.3568C>T p.L1190F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV61861953; called by muse, mutect2, varscan2
- PLEKHG4B | c.1169A>T p.E390V (on ENST00000283426; = p.E746V on NM_052909.5) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV52043864; called by muse, mutect2, varscan2
- PPP1R26 | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.478); catalogued as COSV100778121, COSV63354767; called by muse, mutect2, varscan2
- RGR | c.532A>T p.T178S | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as COSV63893411; called by muse, mutect2, varscan2
- SETD1A | c.4382A>G p.N1461S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.277); catalogued as rs771892048, COSV52685200; called by muse, mutect2
- SHANK1 | c.2460C>A p.N820K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV53243644; called by muse, mutect2, varscan2
- TULP1 | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57691983; called by muse, mutect2, varscan2
- USP9X | c.4603+2T>C p.X1535_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as COSV61066331; called by muse, varscan2
- SENP2 | c.1306del p.H436Mfs*11 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- CDYL2 | c.1455C>G p.L485= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as COSV73653856; called by muse, mutect2, varscan2
- CEP152 | c.1008G>T p.L336= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV57856899; called by muse, mutect2, varscan2
- CYP2F1 | c.1230C>T p.P410= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs148223853; called by muse, mutect2, varscan2
- RNF213 | c.12267T>C p.I4089= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs754723042, COSV60390909; called by muse, mutect2, varscan2
- TEX2 | c.2364C>T p.S788= (on ENST00000583097 / NM_001288733.2; = p.S795= on NM_018469.5) | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV51977661; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.289+1600C>T | Intron (SNP) | VAF 4/19 reads (21%) | catalogued as rs767384791, COSV99141679; called by muse, mutect2
